Somatic mutation profile of tumor specimen MP2PRT-PATLAE-TMP1-A (aliquot MP2PRT-PATLAE-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATLAE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,726 days).
Specimen MP2PRT-PATLAE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 931aa85e-fdfd-488d-b67e-2d82384416a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATLAE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATLAE-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c35d010-922c-4f48-8fb5-cc29b976b70f

The open-access MAF lists 159 somatic variants for this specimen: 110 protein-altering or splice-affecting, 43 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 43, Intron 4, Nonsense Mutation 4, Frame Shift Ins 2, Splice Region 2, 5'Flank 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKFN1 | c.3541G>A p.E1181K (on ENST00000653862; = p.E1034K on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1241729405, COSV73719301; called by muse, mutect2
- ANKRD20A4P | c.1938G>C p.M646I | Missense Mutation (SNP) | VAF 86/388 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1382645703, COSV62006502; called by muse, mutect2, varscan2
- ANO5 | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61090744; called by muse, mutect2, varscan2
- ATP2A3 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs373288442; called by muse, mutect2
- BCR | c.284C>G p.S95W | Missense Mutation (SNP) | VAF 68/559 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV59929310; called by muse, mutect2, varscan2
- CCDC61 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 79/503 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs756423049; called by muse, mutect2, varscan2
- CHD5 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as rs1320265955; called by muse, mutect2, varscan2
- CHRD | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 100/785 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs748780200; called by muse, mutect2, varscan2
- CLNK | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.31); catalogued as rs774485722; called by muse, mutect2
- ETV1 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 146/376 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs773278653, COSV54145546; called by muse, mutect2, varscan2
- EZH2 | c.1672C>T p.P558S (on ENST00000460911 / NM_001203247.2; = p.P563S on NM_004456.5) | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57460117; called by muse, mutect2, varscan2
- FAT2 | c.11023G>C p.E3675Q | Missense Mutation (SNP) | VAF 49/365 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV99942754; called by muse, mutect2, varscan2
- FLNB | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 23/349 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55868962; called by muse, mutect2
- FN1 | c.5194C>G p.Q1732E | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.984); catalogued as COSV60567541; called by muse, mutect2, varscan2
- GCC2 | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100565449; called by muse, mutect2
- GOLGA6L4 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 89/766 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs1432337504; called by muse, mutect2, varscan2
- GPR27 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV55204513; called by muse, mutect2
- HSD11B2 | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 119/373 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as CM981000, COSV52098446, COSV52100214; called by muse, mutect2, varscan2
- KAT2B | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55429571; called by muse, mutect2
- LGALS8 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 36/419 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as rs766088846; called by muse, mutect2
- LMBRD1 | c.1570C>T p.L524F (on ENST00000649011; = p.L502F on NM_018368.4) | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); catalogued as COSV65296400; called by muse, mutect2
- MAP2 | c.4642C>G p.L1548V | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV52307690; called by muse, mutect2
- MEFV | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 82/666 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1206762845, COSV54824487, COSV54825840; called by muse, mutect2
- MTURN | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as COSV61023622, COSV61024464; called by muse, mutect2, varscan2
- MUC16 | c.18665C>T p.S6222F | Missense Mutation (SNP) | VAF 13/371 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV67475124, COSV67488358; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 87/313 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4B1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 120/390 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as rs550081185, COSV58883016; called by muse, mutect2, varscan2
- OR4X2 | c.159C>G p.F53L | Missense Mutation (SNP) | VAF 50/548 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV56583195; called by muse, mutect2
- OR5M10 | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.116); catalogued as COSV101595870, COSV73242389; called by muse, mutect2, varscan2
- P4HB | c.858C>A p.I286= | Splice Region (SNP) | VAF 33/236 reads (14%) | catalogued as rs759143058; called by muse, mutect2, varscan2
- PCDHB11 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 38/491 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs781938950, COSV53377988; called by muse, mutect2
- PI16 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 132/455 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV65321498; called by muse, mutect2, varscan2
- PRKAA2 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV64803149; called by muse, varscan2
- PYGO1 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 45/395 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs770278178, COSV57348397; called by muse, mutect2, varscan2
- RANBP2 | c.2416G>C p.D806H | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs906064531; called by muse, mutect2
- RGPD4 | c.3103G>A p.D1035N | Missense Mutation (SNP) | VAF 55/541 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.475); catalogued as rs1444991538, COSV100736515; called by muse, mutect2, varscan2
- SLC12A1 | c.2486-1G>A p.X829_splice | Splice Site (SNP) | VAF 46/192 reads (24%) | catalogued as rs1382598379; called by muse, mutect2, varscan2
- SLC16A7 | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1386262965; called by muse, mutect2
- STS | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 51/232 reads (22%) | catalogued as COSV54266058; called by muse, varscan2
- SYNM | c.3341C>A p.S1114* | Nonsense Mutation (SNP) | VAF 142/483 reads (29%) | catalogued as COSV99029872; called by muse, mutect2, varscan2
- TM4SF5 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 30/389 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs201854269; called by muse, mutect2
- TRIM32 | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 112/375 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs772903453, COSV57821993; called by muse, mutect2, varscan2
- TTN | c.66331G>C p.E22111Q (on ENST00000591111; = p.E14687Q on NM_003319.4) | Missense Mutation (SNP) | VAF 45/337 reads (13%) | PolyPhen benign (0.295); catalogued as COSV100618220, COSV60165529; called by muse, mutect2, varscan2
- WDR75 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as rs1483211309; called by muse, mutect2, varscan2
- WNT2B | c.796C>T p.R266W (on ENST00000369684 / NM_024494.3; = p.R247W on NM_004185.4) | Missense Mutation (SNP) | VAF 57/510 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs1180086727, COSV56675818; called by muse, mutect2, varscan2
- ZNF256 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 53/422 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs774021457; called by muse, mutect2, varscan2
- ZNF516 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 65/568 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV71586751; called by muse, mutect2, varscan2
- ZNF546 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as COSV61257303; called by muse, mutect2
- ZPBP | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.656); catalogued as rs181173391, COSV99250682; called by muse, mutect2, varscan2
- AADACL3 | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2
- ADGRD2 | c.887C>G p.S296W | Missense Mutation (SNP) | VAF 169/582 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AKAP13 | c.5603C>T p.S1868L (on ENST00000394518 / NM_007200.5; = p.S1872L on NM_006738.6) | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATP10B | c.2841G>C p.E947D | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ATP2A3 | c.1279dup p.Y427Lfs*9 | Frame Shift Ins (INS) | VAF 45/395 reads (11%) | called by mutect2, pindel, varscan2
- C18orf54 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- C2CD4A | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 200/667 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CEP70 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLDN7 | c.429G>C p.Q143H | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.478); called by muse, varscan2
- CNTLN | c.1169G>C p.C390S | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- CSMD1 | c.4510G>C p.D1504H (on ENST00000520002; = p.D1503H on NM_033225.6) | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUL9 | c.4081G>A p.D1361N | Missense Mutation (SNP) | VAF 44/560 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.057); called by muse, mutect2
- CYFIP2 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.775); called by muse, varscan2
- CYP2J2 | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.364); called by muse, mutect2
- DHX36 | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DNAH10 | c.238G>C p.E80Q (on ENST00000409039; = p.E19Q on NM_207437.3) | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- DOCK1 | c.5321G>A p.R1774K | Missense Mutation (SNP) | VAF 58/386 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DOCK7 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- DZIP1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 17/460 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ERI2 | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCC | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 91/374 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- FBXO10 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 128/456 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- GCC2 | c.2592G>A p.M864I | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPR1 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- IDO1 | c.564G>C p.M188I | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IFNA1 | c.137G>C p.R46T | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592654 del ACAATGGCCTCCCCTCACTGTGTCT | Missense Mutation (DEL) | VAF 39/54 reads (72%) | called by pindel, varscan2
- INTU | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2
- ITPRID1 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, varscan2
- LIM2 | c.394G>C p.G132R (on ENST00000596399 / NM_001161748.2; = p.G174R on NM_030657.4) | Missense Mutation (SNP) | VAF 69/439 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MAP9 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2
- MGAM2 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 49/462 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MICAL3 | c.3524C>G p.S1175* | Nonsense Mutation (SNP) | VAF 93/371 reads (25%) | called by muse, mutect2, varscan2
- MLLT10 | c.1960C>G p.L654V (on ENST00000307729 / NM_001195626.3; = p.L670V on NM_004641.3) | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2
- NARS2 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 83/351 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBAS | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 38/504 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- NGRN | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 36/654 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2
- NR3C2 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PAMR1 | c.1953C>A p.S651R (on ENST00000619888 / NM_001001991.3; = p.S668R on NM_015430.4) | Missense Mutation (SNP) | VAF 139/473 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- PATJ | c.2774G>C p.R925T | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- PCSK5 | c.1900+3G>A | Splice Region (SNP) | VAF 49/484 reads (10%) | called by muse, mutect2, varscan2
- PLCH1 | c.360C>G p.I120M (on ENST00000340059 / NM_001130960.2; = p.I132M on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/467 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.54); called by muse, mutect2
- PPP1R9A | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 118/330 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PPP2R1B | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- PRKDC | c.9262C>G p.L3088V | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RCBTB1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- RSF1 | c.4005G>C p.E1335D | Missense Mutation (SNP) | VAF 45/390 reads (12%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN9A | c.1279T>A p.L427I | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2
- SLC16A1 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLCO1C1 | c.1093C>G p.Q365E | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- SYNJ1 | c.2997G>C p.L999F | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- TCHH | c.4382G>A p.R1461K | Missense Mutation (SNP) | VAF 48/538 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- TENM4 | c.5947G>A p.E1983K | Missense Mutation (SNP) | VAF 87/338 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- THAP7 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 24/762 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.175); called by muse, mutect2
- TLR8 | c.3016G>A p.D1006N (on ENST00000218032 / NM_138636.5; = p.D1024N on NM_016610.4) | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- XDH | c.2956G>C p.D986H | Missense Mutation (SNP) | VAF 25/319 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ZNF134 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 20/401 reads (5%) | called by muse, mutect2
- ZNF391 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ZNF493 | c.1910G>C p.G637A | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ZNF546 | c.610C>G p.H204D | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2
- ZNF658 | c.2495_2496insC p.K833Efs*23 | Frame Shift Ins (INS) | VAF 96/330 reads (29%) | called by mutect2, varscan2
- AGBL4 | c.243C>G p.V81= | Silent (SNP) | VAF 32/263 reads (12%) | called by muse, mutect2, varscan2
- ARAP2 | c.3729C>T p.I1243= | Silent (SNP) | VAF 32/332 reads (10%) | called by muse, mutect2
- CACNA1H | c.4947C>G p.L1649= | Silent (SNP) | VAF 30/332 reads (9%) | catalogued as rs1269507586; called by muse, mutect2
- CCDC61 | c.1029C>T p.L343= | Silent (SNP) | VAF 46/497 reads (9%) | catalogued as rs759500360; called by muse, mutect2
- CCDC61 | c.1413C>T p.A471= | Silent (SNP) | VAF 54/354 reads (15%) | catalogued as rs1315962956; called by muse, mutect2, varscan2
- CCNH | c.702G>A p.E234= | Silent (SNP) | VAF 18/282 reads (6%) | catalogued as COSV56925778; called by muse, mutect2
- CHERP | c.714G>A p.Q238= | Silent (SNP) | VAF 242/784 reads (31%) | catalogued as COSV52222915; called by muse, mutect2, varscan2
- DLG2 | c.1386G>A p.Q462= | Silent (SNP) | VAF 18/260 reads (7%) | catalogued as COSV54697542; called by muse, mutect2
- DLX6 | c.858G>C p.T286= | Silent (SNP) | VAF 31/297 reads (10%) | called by muse, mutect2, varscan2
- EMC3 | c.183C>T p.L61= | Silent (SNP) | VAF 24/296 reads (8%) | called by muse, mutect2
- EPHB1 | c.1998G>C p.L666= | Silent (SNP) | VAF 38/434 reads (9%) | catalogued as COSV67673221; called by muse, mutect2
- FADS1 | c.657C>T p.L219= | Silent (SNP) | VAF 32/292 reads (11%) | called by muse, mutect2, varscan2
- FAM171B | c.1497C>T p.N499= | Silent (SNP) | VAF 30/315 reads (10%) | called by muse, mutect2
- FCRL5 | c.1665G>C p.V555= | Silent (SNP) | VAF 52/521 reads (10%) | called by muse, mutect2, varscan2
- FGL1 | c.99C>T p.L33= | Silent (SNP) | VAF 31/320 reads (10%) | catalogued as rs1344097879; called by muse, mutect2, varscan2
- GALR3 | c.789C>T p.F263= | Silent (SNP) | VAF 106/760 reads (14%) | called by muse, mutect2, varscan2
- GAREM2 | c.60C>G p.L20= | Silent (SNP) | VAF 138/460 reads (30%) | called by muse, varscan2
- HCN1 | c.312C>T p.P104= | Silent (SNP) | VAF 210/585 reads (36%) | catalogued as rs750291664; called by muse, varscan2
- HKDC1 | c.312C>T p.H104= | Silent (SNP) | VAF 95/399 reads (24%) | catalogued as rs181028981; called by muse, mutect2, varscan2
- LARGE1 | c.954G>A p.L318= | Silent (SNP) | VAF 42/478 reads (9%) | catalogued as rs746851170; called by muse, mutect2
- LRRC10B | c.237C>G p.L79= | Silent (SNP) | VAF 248/783 reads (32%) | called by muse, mutect2, varscan2
- MYO9A | c.7515G>A p.V2505= | Silent (SNP) | VAF 137/431 reads (32%) | called by muse, mutect2, varscan2
- NDST3 | c.72G>C p.V24= | Silent (SNP) | VAF 84/324 reads (26%) | called by muse, mutect2
- NPIPB11 | c.3459C>G p.P1153= | Silent (SNP) | VAF 169/654 reads (26%) | catalogued as rs757616946; called by muse, mutect2, varscan2
- OR5K3 | c.429G>A p.Q143= | Silent (SNP) | VAF 29/289 reads (10%) | catalogued as COSV67349842; called by muse, mutect2, varscan2
- PAK5 | c.1302G>A p.A434= | Silent (SNP) | VAF 52/584 reads (9%) | catalogued as rs200630536, COSV62037468; called by muse, mutect2
- PGLYRP1 | c.564G>A p.Q188= | Silent (SNP) | VAF 40/324 reads (12%) | called by muse, varscan2
- PGR | c.1317G>A p.V439= | Silent (SNP) | VAF 187/594 reads (31%) | called by muse, mutect2, varscan2
- PRKDC | c.36G>A p.L12= | Silent (SNP) | VAF 51/475 reads (11%) | called by muse, mutect2, varscan2
- PTPRD | c.3963G>C p.L1321= | Silent (SNP) | VAF 17/379 reads (4%) | catalogued as COSV104419479; called by muse, mutect2
- QKI | c.582G>A p.L194= | Silent (SNP) | VAF 77/241 reads (32%) | called by muse, mutect2, varscan2
- RYR2 | c.300C>T p.F100= | Silent (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- SFXN5 | c.57G>C p.S19= | Silent (SNP) | VAF 60/454 reads (13%) | called by muse, mutect2, varscan2
- SHANK2 | c.1383G>A p.A461= | Silent (SNP) | VAF 72/752 reads (10%) | catalogued as rs782599530, COSV53607719; called by muse, mutect2
- SLC16A8 | c.93C>T p.F31= | Silent (SNP) | VAF 34/712 reads (5%) | catalogued as rs778446870; called by muse, mutect2
- SMYD3 | c.90C>G p.L30= | Silent (SNP) | VAF 68/699 reads (10%) | called by muse, mutect2
- STAT3 | c.1239G>A p.L413= | Silent (SNP) | VAF 46/387 reads (12%) | called by muse, mutect2, varscan2
- TMTC2 | c.204C>T p.L68= | Silent (SNP) | VAF 50/546 reads (9%) | called by muse, mutect2
- TPP2 | c.1194G>C p.L398= | Silent (SNP) | VAF 24/340 reads (7%) | catalogued as COSV65751372; called by muse, mutect2
- ULBP3 | c.549C>T p.F183= | Silent (SNP) | VAF 62/648 reads (10%) | called by muse, mutect2
- UNC13B | c.4734G>A p.V1578= | Silent (SNP) | VAF 28/421 reads (7%) | called by muse, mutect2
- ZNF443 | c.1548C>T p.F516= | Silent (SNP) | VAF 28/368 reads (8%) | catalogued as rs771358422; called by muse, mutect2
- ZSWIM4 | c.201C>T p.I67= | Silent (SNP) | VAF 41/386 reads (11%) | catalogued as rs1207670655, COSV54323922; called by muse, mutect2, varscan2
- CC2D2A | c.123+416G>A | Intron (SNP) | VAF 12/322 reads (4%) | called by muse, mutect2
- CCDC28A | chr6:138773540 G>A | 5'Flank (SNP) | VAF 30/516 reads (6%) | catalogued as rs753679294, COSV100236384; called by muse, mutect2
- P4HB | c.*182C>T | 3'UTR (SNP) | VAF 50/546 reads (9%) | called by muse, mutect2
- PAX6 | c.-316-188C>T | Intron (SNP) | VAF 114/357 reads (32%) | catalogued as COSV99570724; called by muse, mutect2, varscan2
- SORBS2 | c.-46+1197C>G | Intron (SNP) | VAF 135/486 reads (28%) | catalogued as rs1475211895; called by muse, mutect2, varscan2
- TMTC1 | c.939-27543G>A | Intron (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
